Gene-level copy-number profile of tumor specimen TCGA-22-4601-01A from TCGA case TCGA-22-4601, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 73.7 years (26,937 days).
Specimen TCGA-22-4601-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.9507ee4a-219b-46c0-a14d-29438dc0d319.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-22-4601-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2 (2 files); ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/344400d9-e339-4cde-a10a-c522b45de429

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 10; copy number 1: 14,363; copy number 2: 36,745; copy number 3: 6,896; copy number 4: 555; copy number 5: 351; copy number 6: 331; copy number 7: 343; copy number 8: 39; copy number 12: 170; copy number 15: 13.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-22-4601-01A-01D-1969-01): tumor purity 0.78, ploidy 1.89, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 10 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:32,580,949–32,846,061, 10 genes (within-gene range 0–1): DPY19L1P1, ZNRF2P1, MIR550A2, MIR550B2, AC018645.3, LINC00997, AC018645.1, AC018645.2, DPY19L1P2, AC018648.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,247 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–150,353,233, 254 genes, copy number 5 (broad region; genes not listed).
- chr2:193,867,722–204,507,672, 212 genes, copy number 6 (broad region; genes not listed).
- chr2:204,668,863–204,678,698, 1 gene, copy number 6: AC007736.1.
- chr3:104,502,700–117,139,389, 181 genes, copy number 5–7 (broad region; genes not listed).
- chr3:118,488,876–118,491,760, 1 gene, copy number 6: AC068633.2.
- chr3:121,593,379–123,274,136, 35 genes, copy number 6 (within-gene range 3–6): FBXO40, HCLS1, RN7SL172P, RNU4-62P, GOLGB1, IQCB1, EAF2, SLC15A2, ILDR1, Y_RNA, CD86, AC068630.1, CASR, HNRNPA1P23, CSTA, CCDC58, FAM162A, WDR5B, AC083798.2, AC083798.1, KPNA1, AC096861.1, AC096861.2, PARP9, DTX3L, PARP15, EIF4BP8, PARP14, HSPBAP1, SLC49A4, LINC02035, SEMA5B, PDIA5, MIR7110, SEC22A.
- chr3:125,082,636–125,212,864, 1 gene, copy number 7 (within-gene range 3–7): SLC12A8.
- chr3:125,151,465–126,673,223, 56 genes, copy number 7: MIR5092, ZNF148, DUTP1, DNAJB6P7, RNU6-232P, SNX4, Y_RNA, Y_RNA, OSBPL11, AF186996.3, AF186996.2, OR7E130P, OR7E29P, OR7E93P, OR7E53P, OR7E97P, AF186996.1, AC092902.4, AC092902.5, AC092902.2, AC092902.1, MIR548I1, RPS3AP14, AC092902.6, SNRPCP11, LINC02614, ENPP7P4, AC092903.2, FAM86JP, ALG1L, AC092903.1, ROPN1B, SLC41A3, AC117422.1, AC079848.1, ALDH1L1, ALDH1L1-AS1, RNU1-30P, ALDH1L1-AS2, AC079848.2, AC016924.1, AC063919.1, AC063919.2, KLF15, CCDC37-DT, CFAP100, AC073439.1, ZXDC, UROC1, CHST13, C3orf22, RNA5SP138, TXNRD3, AC024558.1, NUP210P1, AC078867.1.
- chr3:166,160,021–172,831,229, 121 genes, copy number 7 (broad region; genes not listed).
- chr3:173,396,284–174,286,644, 1 gene, copy number 8 (within-gene range 3–8): NLGN1.
- chr3:173,910,498–185,980,872, 221 genes, copy number 8–15 (broad region; genes not listed).
- chr8:37,516,399–40,402,010, 82 genes, copy number 6 (broad region; genes not listed).
- chr12:66,767–3,286,564, 81 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 14,352. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
